Somatic mutation profile of tumor specimen TCGA-L5-A8NE-01A (aliquot TCGA-L5-A8NE-01A-11D-A37C-09) from TCGA case TCGA-L5-A8NE, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 77.3 years (28,243 days).
Specimen TCGA-L5-A8NE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63814d0a-29ab-4c8e-ad75-27f09c26885e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NE-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NE-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a41db971-dd16-444a-91f4-ee258c9cadc3

The open-access MAF lists 260 somatic variants for this specimen: 211 protein-altering or splice-affecting, 47 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 47, Nonsense Mutation 9, Frame Shift Del 5, Splice Site 2, Splice Region 2, In Frame Del 1, Intron 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.1549A>C p.S517R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV53973026; called by muse, mutect2, varscan2
- ACTL7A | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.375); catalogued as rs748934579; called by muse, mutect2, varscan2
- ADGRE1 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs149695793; called by muse, mutect2, varscan2
- AHSP | c.251A>C p.K84T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100176249; called by muse, mutect2, varscan2
- APC2 | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as rs1375738294; called by muse, mutect2, varscan2
- ASB17 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.935); catalogued as COSV52410254; called by muse, mutect2, varscan2
- ATP10D | c.4192T>G p.L1398V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV56700032; called by muse, mutect2, varscan2
- AUTS2 | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1437864529, COSV61387629; called by mutect2, varscan2
- BTBD2 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs36020359; called by muse, mutect2, varscan2
- CDH6 | c.1061T>G p.V354G | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV54070882; called by muse, mutect2, varscan2
- CDPF1 | c.225G>A p.P75= | Splice Region (SNP) | VAF 12/51 reads (24%) | catalogued as rs763307321; called by muse, mutect2, varscan2
- CHST9 | c.986A>C p.K329T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs745315555, COSV52434844, COSV99410344; called by muse, mutect2, varscan2
- CHSY3 | c.2096T>G p.L699R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.348); catalogued as COSV100518293, COSV59279691; called by muse, mutect2
- CPM | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 52/592 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100614993; called by muse, mutect2
- CRAT | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs527857954; called by muse, mutect2, varscan2
- DACH1 | c.1373A>G p.N458S (on ENST00000619232 / NM_001366712.1; = p.N406S on NM_080759.6) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV57522261; called by muse, mutect2, varscan2
- DCC | c.2365A>G p.S789G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as rs1360222053, COSV59125955; called by mutect2, varscan2
- DDC | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs761191841, COSV63565642; called by muse, mutect2, varscan2
- DLG2 | c.105A>C p.E35D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV65832294, COSV65853967; called by muse, mutect2, varscan2
- DNAH5 | c.6457T>G p.F2153V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1395905411, COSV54261757; called by muse, mutect2, varscan2
- DOCK2 | c.3017A>C p.K1006T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs763218061, COSV56942171, COSV56954214; called by muse, mutect2, varscan2
- DROSHA | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as rs1186040397, COSV100757688; called by muse, mutect2, varscan2
- EGFLAM | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV100380993; called by muse, mutect2, varscan2
- EPHA3 | c.1568A>C p.K523T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV60719793, COSV60731934; called by muse, mutect2, varscan2
- EVL | c.560del p.P187Hfs*41 (on ENST00000402714 / NM_001330221.2; = p.P189Hfs*41 on NM_016337.3) | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs746606863; called by mutect2, varscan2
- FGFR4 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as rs140492176; called by muse, mutect2, varscan2
- FIGNL1 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100794905; called by muse, mutect2, varscan2
- FLG | c.4615A>C p.S1539R | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs536230632, COSV100912077, COSV64237938; called by muse, mutect2, varscan2
- FLG2 | c.2590A>C p.S864R | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV66170521; called by muse, mutect2, varscan2
- FLRT2 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58142665; called by muse, mutect2, varscan2
- FREM1 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs1564063185; called by muse, mutect2, varscan2
- FURIN | c.667+1G>A p.X223_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as rs1475526920, COSV51580070; called by mutect2, varscan2
- GALNT13 | c.82T>G p.F28V | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV101223646, COSV67222532; called by muse, mutect2, varscan2
- GPR83 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs200087801, COSV54717331; called by muse, mutect2, varscan2
- GPRC5B | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771728943, COSV56026268; called by muse, mutect2, varscan2
- GUCY1A2 | c.1533A>C p.Q511H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.339); catalogued as rs1281367945; called by muse, mutect2, varscan2
- HMCN1 | c.11642G>A p.G3881D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs748722327; called by muse, mutect2, varscan2
- HMGB4 | c.219A>C p.E73D | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99592467; called by muse, mutect2, varscan2
- HMGB4 | c.433A>G p.R145G | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV53876758; called by muse, mutect2, varscan2
- HPGDS | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as COSV54773281; called by muse, mutect2, varscan2
- IMPG2 | c.1032A>C p.K344N | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.69); PolyPhen benign (0.113); catalogued as rs34375459; called by muse, mutect2, varscan2
- KCNQ3 | c.848A>G p.E283G | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66465755; called by muse, mutect2, varscan2
- KCNU1 | c.740A>C p.N247T | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67759744; called by muse, mutect2, varscan2
- KIF4B | c.2144A>C p.K715T | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs771438775; called by muse, mutect2, varscan2
- MAT1A | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs779094715, CM055977, COSV64746051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC15 | c.945A>C p.E315D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV99846071, COSV99846078; called by muse, varscan2
- MYH2 | c.5304C>T p.A1768= | Splice Region (SNP) | VAF 52/70 reads (74%) | catalogued as rs562803081, COSV55442713; called by muse, mutect2, varscan2
- NBEA | c.468A>C p.E156D | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV100076744; called by muse, mutect2, varscan2
- NDN | c.398A>G p.K133R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.759); catalogued as rs754567876; called by muse, mutect2
- OLFM4 | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54576255, COSV54577839, COSV54579863; called by muse, mutect2, varscan2
- OR10R2 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.052); catalogued as COSV63768885; called by muse, mutect2, varscan2
- OR13C3 | c.349T>C p.S117P | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV101053332; called by muse, mutect2, varscan2
- OR1C1 | c.151T>G p.F51V | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as COSV68716175; called by muse, mutect2, varscan2
- OR52A5 | c.455T>A p.L152H | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56616658; called by muse, mutect2, varscan2
- OR5K3 | c.147T>G p.I49M | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67350829; called by muse, mutect2, varscan2
- OR6Y1 | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV56928024; called by muse, mutect2, varscan2
- OTOF | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs370225374; called by muse, mutect2, varscan2
- OXR1 | c.2228G>T p.G743V (on ENST00000442977 / NM_001198532.1; = p.G715V on NM_018002.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.027); catalogued as rs1259975490; called by muse, mutect2, varscan2
- PEG3 | c.4276G>T p.D1426Y | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV55642593; called by muse, mutect2, varscan2
- PHKA2 | c.3080C>T p.A1027V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs375184186; called by muse, mutect2, varscan2
- PREX2 | c.3470A>C p.K1157T | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1425336743, COSV99908973; called by muse, mutect2, varscan2
- PTPRD | c.5387A>G p.Q1796R | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV61956896; called by muse, mutect2, varscan2
- RIMBP2 | c.2452G>A p.V818M | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372504138; called by muse, mutect2, varscan2
- RYR1 | c.9905del p.P3302Hfs*19 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs749656679; called by mutect2, varscan2
- RYR2 | c.2480T>C p.L827P | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63711718; called by muse, mutect2, varscan2
- RYR3 | c.10694C>T p.T3565M (on ENST00000389232; = p.T3566M on NM_001036.6) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as rs373357553; called by muse, mutect2, varscan2
- SCNN1G | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as rs775500246, COSV55598002; called by muse, mutect2, varscan2
- SFI1 | c.1997G>A p.R666Q (on ENST00000400288 / NM_001007467.3; = p.R635Q on NM_014775.4) | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs567259192, COSV66292698; called by muse, mutect2, varscan2
- SFXN4 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.53); catalogued as rs1245766113; called by muse, mutect2, varscan2
- SLC35F1 | c.359A>C p.N120T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV64506146, COSV64510667; called by muse, mutect2, varscan2
- SLITRK3 | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99579154; called by muse, mutect2, varscan2
- SMTNL1 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1285722443; called by muse, mutect2
- STEAP3 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs978221233; called by muse, mutect2, varscan2
- TDRD5 | c.2320T>G p.S774A | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs1326690365; called by muse, mutect2, varscan2
- TIMD4 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs774551130, COSV50858482; called by muse, mutect2, varscan2
- TNFSF14 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as rs772372888, COSV55590939; called by muse, mutect2, varscan2
- TNRC18 | c.7172C>T p.P2391L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs767310790; called by muse, mutect2, varscan2
- TTC27 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as COSV100513027, COSV58655505; called by muse, mutect2, varscan2
- VEPH1 | c.2043A>C p.E681D | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as COSV62876728; called by muse, mutect2, varscan2
- VIRMA | c.5302C>T p.R1768W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776496785, COSV52582224; called by muse, mutect2, varscan2
- WSCD2 | c.948T>G p.S316R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs758017532, COSV99775139; called by muse, mutect2, varscan2
- ZBED9 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV71729327; called by muse, mutect2, varscan2
- ZC3H7A | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV63270656; called by muse, mutect2, varscan2
- ZNF257 | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV71306174; called by muse, mutect2, varscan2
- ZNF283 | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs1320634504; called by muse, varscan2
- ZNF454 | c.776T>A p.L259H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100194846; called by muse, mutect2, varscan2
- ZNF536 | c.1973A>C p.K658T | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV62834571; called by muse, mutect2, varscan2
- ZNF560 | c.578A>C p.N193T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV56868180; called by muse, mutect2, varscan2
- ZNF569 | c.1708A>G p.R570G | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV57593386; called by muse, mutect2, varscan2
- ZNF721 | c.113G>A p.R38K (on ENST00000338977; = p.R50K on NM_133474.4) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV59095569; called by muse, mutect2, varscan2
- ZNF804A | c.2548A>C p.S850R | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100170831; called by muse, mutect2, varscan2
- ABCC9 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABI3BP | c.1959T>G p.F653L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAN | c.6010T>A p.F2004I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- ACSM6 | c.756-2A>T p.X252_splice | Splice Site (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- ACTL9 | c.1000T>G p.L334V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AL136295.1 | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ALKBH2 | c.716C>G p.P239R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMIGO3 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ANKRA2 | c.327T>G p.I109M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ATP10B | c.2979A>C p.E993D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- B4GALT1 | c.913A>C p.N305H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BANK1 | c.2199A>C p.E733D | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BAZ1B | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- BCL2L12 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- C10orf71 | c.14A>C p.N5T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- CCDC180 | c.245A>C p.N82T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH11 | c.946T>G p.F316V | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH11 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLEC6A | c.503A>T p.E168V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNOT1 | c.3111C>A p.S1037R | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.243); called by muse, mutect2
- COX20 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.6428T>C p.L2143P (on ENST00000297405 / NM_001363185.1; = p.L2039P on NM_052900.3) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CTNNA1 | c.1123A>G p.T375A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.093); called by muse, mutect2
- CYLC1 | c.1363A>C p.K455Q | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CYTH2 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- DHX9 | c.1814A>T p.D605V | Missense Mutation (SNP) | VAF 69/96 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DNAH12 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK3 | c.2888T>A p.L963H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOCK3 | c.4075T>G p.F1359V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DPP3 | c.157T>C p.S53P | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ELF4 | c.1739del p.P580Qfs*30 | Frame Shift Del (DEL) | VAF 34/55 reads (62%) | called by mutect2, pindel, varscan2
- EML4 | c.707T>A p.I236N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC2 | c.2540G>A p.S847N | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.795); called by muse, mutect2
- FAM117A | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- FAM193B | c.2230T>A p.L744M | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- FAM217B | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM47C | c.468G>C p.E156D | Missense Mutation (SNP) | VAF 57/77 reads (74%) | SIFT tolerated (0.5); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- FBXO21 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GABRA1 | c.70A>G p.R24G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GALNT18 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GLIPR1 | c.518G>C p.C173S | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS1BP3 | c.446A>T p.D149V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by mutect2, varscan2
- HS6ST2 | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IPP | c.912G>A p.W304* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- ITK | c.1307A>C p.E436A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IVL | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2
- IVL | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- KCNA1 | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2
- KCNA3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KCTD15 | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- KMT2E | c.3467A>G p.K1156R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- LAD1 | c.505_506del p.R169Efs*23 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by pindel, varscan2
- LAMA2 | c.2208A>C p.E736D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LAMA2 | c.9298C>T p.P3100S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- LRRN3 | c.728T>C p.F243S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LSM14A | c.641G>T p.R214I | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MAP2 | c.4425A>C p.E1475D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- MDGA2 | c.3008T>G p.V1003G (on ENST00000399232 / NM_001113498.2; = p.V705G on NM_182830.4) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MROH9 | c.1465T>G p.F489V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MRPL39 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2
- NACA | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- NANOG | c.694A>G p.N232D | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- NCKAP5 | c.1264A>C p.T422P | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NFX1 | c.2968G>A p.A990T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- NIPBL | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NME8 | c.1286A>C p.N429T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOVA1 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NPS | c.191A>C p.K64T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NRG1 | c.299A>C p.N100T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NRXN1 | c.1678A>G p.T560A | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OR2A1 | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- OR52K2 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5P3 | c.86T>G p.L29R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- OR5V1 | c.133A>C p.I45L | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR6T1 | c.904A>T p.R302* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- PCDH11X | c.1577A>C p.K526T | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PCDH18 | c.1299G>T p.L433F | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH18 | c.326A>C p.D109A | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.15188dup p.V5064Gfs*12 | Frame Shift Ins (INS) | VAF 10/29 reads (34%) | called by mutect2, varscan2
- PKD1L1 | c.1565_1566del p.T522Rfs*17 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by pindel, varscan2
- PKMYT1 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP1R17 | c.172T>G p.S58A | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRAMEF14 | c.394A>G p.R132G | Missense Mutation (SNP) | VAF 158/330 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PREX2 | c.2256T>G p.D752E | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PRLR | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PZP | c.2966A>G p.N989S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- RDX | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMS2 | c.1457A>C p.D486A (on ENST00000666250 / NM_001348490.2; = p.D294A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- RNF217 | c.1384T>G p.F462V (on ENST00000521654 / NM_001286398.2; = p.F170V on NM_152553.5) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPA4 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 11/13 reads (85%) | called by muse, mutect2, varscan2
- RYR3 | c.2227A>C p.S743R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN4B | c.100T>C p.S34P | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- SEC14L5 | c.1614G>A p.W538* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- SERPINB13 | c.263A>C p.K88T | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLC25A33 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC5A12 | c.1270T>G p.F424V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- SLC6A11 | c.542T>G p.V181G | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SNX13 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- SPEF2 | c.958_961delinsT p.I320_A321delinsS | In Frame Del (DEL) | VAF 18/57 reads (32%) | called by pindel, varscan2*
- SRPX | c.458T>G p.L153W | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STEAP4 | c.1218C>G p.F406L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- STIM1 | c.813G>C p.E271D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TAF1C | c.197T>A p.L66H | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TARS2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBC1D32 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- TENM2 | c.5003A>T p.K1668I (on ENST00000518659 / NM_001122679.2; = p.K1429I on NM_001080428.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- THSD7B | c.1891A>C p.T631P | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- TNS4 | c.1058T>C p.L353P | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRDMT1 | c.193T>G p.F65V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- TRIM62 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- TUB | c.415G>C p.A139P (on ENST00000299506 / NM_177972.3; = p.A194P on NM_003320.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- TUBA3C | c.506T>G p.F169C | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ULK3 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- VN1R2 | c.575A>T p.N192I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- ZC3H12C | c.100T>G p.L34V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ZNF236 | c.2975A>G p.E992G | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF543 | c.1598A>T p.K533M | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ZNF667 | c.1485A>C p.E495D | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- ZNF681 | c.556A>C p.T186P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF804A | c.748A>C p.S250R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ACSM2B | c.1107T>G p.T369= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV61657267, COSV61658124; called by muse, mutect2, varscan2
- ALG10B | c.1251C>T p.Y417= | Silent (SNP) | VAF 28/41 reads (68%) | catalogued as rs753993282; called by muse, mutect2, varscan2
- ANKRA2 | c.831A>G p.E277= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP5 | c.45C>T p.I15= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- BCHE | c.1314A>C p.S438= | Silent (SNP) | VAF 46/64 reads (72%) | called by muse, mutect2, varscan2
- BCHE | c.150T>G p.G50= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.147C>T p.I49= | Silent (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- CELSR3 | c.2148T>G p.R716= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- CHST15 | c.160T>C p.L54= | Silent (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- CTBP2 | c.843A>G p.L281= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- DDR1 | c.636C>T p.D212= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- DNAJC6 | c.2700C>G p.A900= | Silent (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- ELMO1 | c.6G>T p.P2= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV60326711; called by muse, mutect2, varscan2
- ELOA2 | c.690T>C p.S230= | Silent (SNP) | VAF 34/47 reads (72%) | called by muse, mutect2, varscan2
- HBE1 | c.249G>A p.K83= | Silent (SNP) | VAF 41/69 reads (59%) | called by muse, mutect2, varscan2
- ITGAX | c.1569G>A p.A523= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as rs144979651; called by muse, mutect2, varscan2
- ITGAX | c.2943T>C p.A981= | Silent (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- ITK | c.63T>G p.T21= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV70065410; called by muse, mutect2, varscan2
- KAT6B | c.5880G>A p.T1960= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs200498444; called by muse, mutect2, varscan2
- MARCHF11 | c.912A>G p.A304= | Silent (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2, varscan2
- MATN3 | c.663C>T p.G221= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs369658011; called by muse, mutect2, varscan2
- MMP25 | c.312G>T p.R104= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs143114141; called by muse, mutect2
- MPDZ | c.1698G>A p.G566= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs749464800; called by muse, mutect2, varscan2
- NLRC5 | c.3819C>T p.S1273= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs367867217; called by muse, mutect2, varscan2
- NLRP1 | c.2400C>T p.L800= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs200218955; called by muse, mutect2, varscan2
- OR5T1 | c.741A>G p.R247= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as COSV99080591; called by muse, mutect2, varscan2
- PEG3 | c.2937T>C p.A979= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV55645486; called by muse, mutect2, varscan2
- PKP4 | c.1929C>A p.S643= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100733730; called by muse, mutect2, varscan2
- PLXNC1 | c.1098C>T p.I366= | Silent (SNP) | VAF 49/74 reads (66%) | catalogued as rs141950146, COSV99312417; called by muse, mutect2, varscan2
- RNF103 | c.507C>T p.V169= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1283464991; called by muse, mutect2
- SNX29 | c.2388C>T p.S796= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs754154137, COSV100028759; called by muse, mutect2
- SULT1E1 | c.884A>G p.*295= | Silent (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- TAF10 | c.510C>T p.A170= | Silent (SNP) | VAF 8/17 reads (47%) | called by mutect2, varscan2
- TBC1D10B | c.972C>T p.P324= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs749347889, COSV69505050; called by muse, mutect2, varscan2
- TBXA2R | c.192C>A p.L64= | Silent (SNP) | VAF 35/142 reads (25%) | called by muse, mutect2, varscan2
- TCERG1L | c.472A>C p.R158= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- THEM5 | c.222G>A p.L74= | Silent (SNP) | VAF 32/52 reads (62%) | called by muse, mutect2, varscan2
- TMEM205 | c.138C>T p.F46= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs1209840055, COSV61514720; called by muse, mutect2, varscan2
- TRIM58 | c.1434T>C p.A478= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2
- TTN | c.16038T>C p.T5346= (on ENST00000591111; = p.T4419= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs879099217; ClinVar: likely benign; called by muse, mutect2, varscan2
- VCAN | c.1359A>G p.S453= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- WASF1 | c.498G>A p.L166= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs758077376; called by muse, mutect2, varscan2
- WDR7 | c.2814T>C p.T938= | Silent (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- ZNF160 | c.801T>A p.T267= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- ZNF283 | c.363C>A p.T121= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs1353324237; called by muse, varscan2
- ZNF532 | c.423C>T p.D141= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs372741032; called by muse, mutect2, varscan2
- ZNF676 | c.891C>A p.V297= (on ENST00000650058; = p.V265= on NM_001001411.3) | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV101236262; called by muse, mutect2, varscan2
- LAMA4 | c.503+1436T>G | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1192del | RNA (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
